TCGA case TCGA-KK-A7AQ — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cecf4ee9-7610-4f47-a825-7fde8233b75d

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 62.2 years (22,731 days); Year of diagnosis: 2010; Method of diagnosis: Core Biopsy; AJCC clinical T: T2a; AJCC clinical M: M0; AJCC pathologic T: T2c; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason grade tertiary: Pattern 5; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 11; Tumor level prostate: Apex / Middle; Zone of origin prostate: Peripheral zone.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Abiraterone + Leuprolide Acetate; Days to treatment start: 1,219 days (3.3 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 38 (initial diagnosis): Days to imaging: 38 days; Imaging type: MRI; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 1,217 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 1,217 days (3.3 years).
- Days to follow up: 1,386 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,610 days (4.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.1 ng/mL (day 1,385).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KK-A7AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-KK-A7AQ-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KK-A7AQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KK-A7AQ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 320 mg.
  Slide TCGA-KK-A7AQ-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: Yes.
- Tumor levels: Tumor level: Apex; Tumor level: Middle.
- Stage record, Psa: PSA most recent results: 0.1.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 3; Gleason pattern tertiary: 5.
- New tumor event: New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,610 days; disease-specific survival: no event (censored), 1,610 days; disease-free interval: event (new tumor event after initially disease-free), 1,217 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,217 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KK-A7AQ-01A-11D-A33S-01): tumor purity 0.76, ploidy 1.89, whole-genome doublings 0.
